Somatic mutation profile of tumor specimen TARGET-20-PARSAN-09A (aliquot TARGET-20-PARSAN-09A-01D) from TARGET case TARGET-20-PARSAN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,420 days).
Specimen TARGET-20-PARSAN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7ec8671-345f-47ed-805e-ed5602eebcd6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARSAN-14A (Bone Marrow Normal), aliquot TARGET-20-PARSAN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b79ddaf9-f66c-4ab0-b580-fb970ceda335

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52462785; called by muse, mutect2, varscan2
- SIN3A | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as COSV64583877; called by muse, mutect2, varscan2
